Somatic mutation profile of tumor specimen 0DBQFC from CCDI case PBBLEY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,189 days).
Specimen 0DBQFC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd3182b7-9e36-4ebc-8025-cbd88d14a389.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBQF8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94b807bc-eb04-4e56-a15b-77e818923a63

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBEC3B | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 3/384 reads (1%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 68/2056 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KRT18 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 64/1798 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SMARCB1 | c.535del p.D179Ifs*4 (on ENST00000263121; = p.D225Ifs*4 on NM_003073.5) | Frame Shift Del (DEL) | VAF 281/426 reads (66%) | called by mutect2, varscan2
- TTF1 | c.2414C>A p.S805Y | Missense Mutation (SNP) | VAF 106/1188 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ZFP36L2 | c.528C>T p.F176= | Silent (SNP) | VAF 26/862 reads (3%) | catalogued as COSV56698487; called by muse, mutect2
- ZIC1 | c.648C>T p.Y216= | Silent (SNP) | VAF 47/917 reads (5%) | called by muse, mutect2
- ZIC2 | c.205C>T p.L69= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as rs1000392329; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 39/277 reads (14%) | called by muse, varscan2
